Somatic mutation profile of tumor specimen MP2PRT-PATJZE-TMP1-A (aliquot MP2PRT-PATJZE-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATJZE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,042 days).
Specimen MP2PRT-PATJZE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0f0a04c-689f-4f74-8444-d2c1cd244d2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATJZE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATJZE-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4897dc6-a14e-491a-bb26-b322f70e18af

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IREB2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 13/376 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV51925269; called by muse, mutect2
- SLC25A1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 242/771 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs782305001; called by muse, mutect2, varscan2
- CLSTN2 | c.2239C>T p.Q747* | Nonsense Mutation (SNP) | VAF 94/279 reads (34%) | called by muse, mutect2, varscan2
- IGHV1-45 | c.351_353del p.R117del | In Frame Del (DEL) | VAF 45/93 reads (48%) | called by mutect2, pindel*
- OSBP2 | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 177/543 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SHISA2 | c.727C>A p.L243M | Missense Mutation (SNP) | VAF 75/537 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TNIK | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 92/276 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBTFL1 | c.189T>A p.I63= | Silent (SNP) | VAF 108/315 reads (34%) | called by muse, mutect2, varscan2
